Somatic mutation profile of tumor specimen MBCProject_0124_T1_WES (aliquot MBCProject_0124_T1_WES_1) from CMI case MBCProject_0124, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.4 years (14,763 days).
Specimen MBCProject_0124_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 432b6e96-1213-4b1a-869f-630ef717d63f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0124_SALIVA (Saliva), aliquot MBCProject_0124_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d576c4f8-c702-48ca-9bc6-d840edb4a940

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 4, 3'UTR 3, RNA 2, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 35/108 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.249); catalogued as rs1238245063; called by muse, mutect2
- FAM83H | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs782448672, COSV62028946; called by muse, mutect2
- GLDC | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58682230; called by muse, mutect2, varscan2
- MTO1 | c.1156A>C p.M386L | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs997481152, COSV64773224; called by muse, varscan2
- PCDHGA9 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.268); catalogued as rs747720731; called by mutect2, varscan2
- UBN2 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 29/541 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.747); catalogued as COSV99943954; called by muse, mutect2
- ASPM | c.8379G>C p.M2793I | Missense Mutation (SNP) | VAF 65/555 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC120 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2
- DGKH | c.2254A>G p.T752A | Missense Mutation (SNP) | VAF 48/376 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR1 | c.4594T>G p.S1532A (on ENST00000354582; = p.S1517A on NM_002222.7) | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- KRTAP16-1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PASD1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SNX24 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC1 | c.4782C>T p.I1594= | Silent (SNP) | VAF 30/263 reads (11%) | catalogued as rs192870385, COSV51937261; called by muse, mutect2, varscan2
- C4BPB | c.410-1081A>C | Intron (SNP) | VAF 7/80 reads (9%) | catalogued as rs1262106767; called by muse, mutect2, varscan2
- C9orf92 | n.254G>A | RNA (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 27/190 reads (14%) | catalogued as rs1291738365; called by muse, mutect2
- FAM161A | c.*555T>C | 3'UTR (SNP) | VAF 9/112 reads (8%) | catalogued as rs1195163165; called by muse, mutect2
- FRMD1 | chr6:168081501 G>A | 5'Flank (SNP) | VAF 4/43 reads (9%) | catalogued as rs746121347; called by mutect2, varscan2
- KIFAP3 | c.320-2469C>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as rs1210250729; called by muse, mutect2
- METTL2B | c.*721A>G | 3'UTR (SNP) | VAF 22/262 reads (8%) | catalogued as rs1386784188, COSV52310130; called by muse, mutect2
- RBBP4 | c.1212+659T>C | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as rs1020724420; called by muse, varscan2
- SHROOM4 | c.*1378T>G | 3'UTR (SNP) | VAF 10/90 reads (11%) | catalogued as rs1557245541; called by muse, varscan2
- STAG3L2 | n.1023G>T | RNA (SNP) | VAF 34/282 reads (12%) | catalogued as rs1554426472; called by muse, mutect2
